CCDI case PBBJPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b704c922-3001-4ec6-83e8-3df7a3bc78d2

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.8 years (1,040 days).

Biospecimens (3 samples)
- Sample 0DAF7A: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAF7Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAF7S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
